Somatic mutation profile of tumor specimen TARGET-10-PATGBY-09A (aliquot TARGET-10-PATGBY-09A-01D) from TARGET case TARGET-10-PATGBY, project TARGET-ALL-P2 (Acute Lymphoblastic Leukemia - Phase II). Sex at birth: male; Vital status: Alive; Primary diagnosis: Acute lymphocytic leukemia; Tissue or organ of origin: Bone marrow; Age at diagnosis: 21.1 years (7,715 days).
Specimen TARGET-10-PATGBY-09A: Sample type: Primary Blood Derived Cancer - Bone Marrow; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Bone Marrow NOS.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 3d2e5df4-5e75-441a-ab1a-cc5f1a523620.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TARGET-10-PATGBY-10A (Blood Derived Normal), aliquot TARGET-10-PATGBY-10A-01D; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/f6a55460-9475-4306-8766-97469d1b1ee0

The open-access MAF lists 25 somatic variants for this specimen: 17 protein-altering or splice-affecting, 3 silent, 5 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 14, Silent 3, Intron 3, 3'UTR 2, Nonsense Mutation 1, In Frame Ins 1, Frame Shift Ins 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- ABLIM1 | c.2248C>T p.R750W | Missense Mutation (SNP) | VAF 25/61 reads (41%) | SIFT tolerated (0.18); PolyPhen benign (0.005); catalogued as rs772414770, COSV53301185; called by muse, mutect2, varscan2
- AHNAK2 | c.1911A>T p.E637D | Missense Mutation (SNP) | VAF 48/116 reads (41%) | SIFT tolerated (0.45); PolyPhen benign (0.244); catalogued as COSV60909155; called by muse, mutect2, varscan2
- CABIN1 | c.5363G>A p.R1788Q | Missense Mutation (SNP) | VAF 28/50 reads (56%) | SIFT tolerated, low confidence (0.33); PolyPhen benign (0); catalogued as rs751722644, COSV54078526; called by muse, mutect2, varscan2
- DLGAP1 | c.1426G>A p.V476M | Missense Mutation (SNP) | VAF 38/71 reads (54%) | SIFT tolerated (0.82); PolyPhen benign (0.158); catalogued as rs748701251, COSV59787361, COSV59822489; called by muse, mutect2, varscan2
- IL23R | c.307G>A p.A103T | Missense Mutation (SNP) | VAF 48/106 reads (45%) | SIFT deleterious (0); PolyPhen probably damaging (0.974); catalogued as COSV61373092; called by muse, mutect2, varscan2
- KRTAP10-3 | c.557C>T p.P186L | Missense Mutation (SNP) | VAF 12/32 reads (38%) | SIFT deleterious (0); PolyPhen benign (0.133); catalogued as COSV59953926; called by muse, mutect2, varscan2
- LCP2 | c.1519A>G p.K507E | Missense Mutation (SNP) | VAF 59/144 reads (41%) | SIFT deleterious (0.01); PolyPhen benign (0.269); catalogued as COSV50447194; called by muse, mutect2, varscan2
- NOTCH1 | c.7177C>T p.Q2393* | Nonsense Mutation (SNP) | VAF 19/38 reads (50%) | catalogued as COSV53033066; called by muse, mutect2, varscan2
- NOTCH1 | c.4850_4851insTGTAGG p.F1617_P1618insVG | In Frame Ins (INS) | VAF 5/20 reads (25%) | catalogued as COSV53033071, COSV53045239, COSV53052969, COSV53065728, COSV53095589; called by mutect2, pindel, varscan2
- PHF6 | c.129dup p.K44* | Frame Shift Ins (INS) | VAF 37/61 reads (61%) | catalogued as COSV59699798; called by mutect2, pindel, varscan2
- RPL4 | c.82T>C p.F28L | Missense Mutation (SNP) | VAF 19/42 reads (45%) | SIFT tolerated (0.09); PolyPhen possibly damaging (0.768); catalogued as COSV57178603; called by muse, mutect2, varscan2
- SLC22A3 | c.1230T>G p.F410L | Missense Mutation (SNP) | VAF 15/39 reads (38%) | SIFT tolerated (0.45); PolyPhen benign (0.048); catalogued as COSV51710637; called by muse, mutect2, varscan2
- TRPC7 | c.2215A>C p.S739R | Missense Mutation (SNP) | VAF 27/59 reads (46%) | SIFT tolerated (0.6); PolyPhen benign (0); catalogued as COSV61453805; called by muse, mutect2, varscan2
- HERC2 | c.13519G>T p.G4507W | Missense Mutation (SNP) | VAF 3/41 reads (7%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2
- MOS | c.119T>A p.L40H | Missense Mutation (SNP) | VAF 4/58 reads (7%) | SIFT tolerated (0.54); PolyPhen benign (0.01); called by muse, mutect2
- MUC19 | c.1172C>T p.S391F | Missense Mutation (SNP) | VAF 11/24 reads (46%) | SIFT tolerated (0.14); PolyPhen possibly damaging (0.692); called by muse, mutect2, varscan2
- TMEM170A | c.305G>C p.S102T | Missense Mutation (SNP) | VAF 4/54 reads (7%) | SIFT tolerated (0.05); PolyPhen probably damaging (0.973); called by muse, mutect2
- IGHM | c.12C>T p.S4= | Silent (SNP) | VAF 3/45 reads (7%) | catalogued as rs367763128; called by muse, mutect2
- TRIM42 | c.804G>A p.S268= | Silent (SNP) | VAF 42/77 reads (55%) | catalogued as rs114287544; called by muse, mutect2, varscan2
- TUBB | c.936C>T p.T312= | Silent (SNP) | VAF 20/36 reads (56%) | catalogued as rs532302557, COSV58357221; called by muse, mutect2, varscan2
- CA11 | c.*57A>T | 3'UTR (SNP) | VAF 25/50 reads (50%) | called by muse, mutect2, varscan2
- NDUFA11 | c.314-100G>T | Intron (SNP) | VAF 5/11 reads (45%) | catalogued as rs577909240; called by muse, varscan2
- SNX17 | c.*794T>C | 3'UTR (SNP) | VAF 15/97 reads (15%) | called by muse, mutect2, varscan2
- SPINK7 | c.87+28T>C | Intron (SNP) | VAF 20/47 reads (43%) | called by muse, mutect2, varscan2
- ZNF324B | c.238+41G>A | Intron (SNP) | VAF 19/55 reads (35%) | called by muse, mutect2, varscan2
